Somatic mutation profile of tumor specimen 0DLHP3 from CCDI case PBBZHJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,016 days).
Specimen 0DLHP3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24a563f5-3550-4197-b12a-dbfda6658f0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11e062a7-4cbf-4284-88a7-1e17ae551d9a

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs962936073, COSV99489777; called by muse, mutect2, varscan2
- CEP250 | c.6400A>G p.M2134V | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs199936529; called by muse, mutect2, varscan2
- CSPG4 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs199534811; called by muse, varscan2
- PGAP2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 33/469 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs760866870; called by muse, mutect2
- DDX21 | c.468T>C p.H156= | Silent (SNP) | VAF 319/796 reads (40%) | called by muse, mutect2, varscan2
- CD244 | c.*63A>G | 3'UTR (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
